FM case AD41 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/4718d5a4-3e9c-4df2-b366-0cc0f3820c5d

Male, 55.6 years: Renal cell carcinoma, NOS (ICD-O-3 8312/3) of the kidney; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
